Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A2P4, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A2P4-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/HISTORY OF PRESENT ILLNESS (INCLUDING PREOP AND POSTOP DIAGNOSIS): Thyroid nodule

PROCEDURE: Thyroidectomy

SPECIFIC CLINICAL QUESTION TO ANSWER: Not answered

OUTSIDE TISSUE DIAGNOSIS ON THIS SPECIMEN: No

PRIOR CANCER/MALIGNANCY/TUMOR: No

CHEMORADIATION THERAPY: No

HISTORY OF ORGAN TRANSPLANT: No

HISTORY OF IMMUNOSUPPRESSION: No

ANY OTHER UNDERLYING DISEASES: No

**FINAL DIAGNOSIS:****PART 1: THYROID GLAND, LEFT LOBE, LOBECTOMY (14 GRAMS) -**

- A. PAPILLARY THYROID CARCINOMA, 3.3 CM, WITH DOMINANT FOLLICULAR GROWTH PATTERN (see comment).
- B. EXTRATHYROIDAL EXTENSION IS ABSENT.
- C. VASCULAR INVASION IS ABSENT.
- D. CARCINOMA IS 0.1 CM FROM MARGIN.
- E. PATHOLOGIC STAGE: T2.

PART 2: THYROID GLAND, RIGHT LOBE, LOBECTOMY (2.6 AND 0.7 GRAMS) - BENIGN THYROID TISSUE.**COMMENT:**

Previously, fine needle aspiration of the left thyroid lobe mutation (see addendum for further details).

It was shown to be positive for HRAS

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Left Lobe
TUMOR FOCALITY:	Unifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 3.3 cm
HISTOLOGIC TYPE**:	Papillary carcinoma
PRIMARY TUMOR (pT):	pT2
REGIONAL LYMPH NODES (pN):	pNX
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Not identified
MARGINS:	Margins uninvolved by carcinoma Distance of invasive carcinoma to closest margin: 1 mm
LYMPH-VASCULAR INVASION:	Not identified

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS c73.9 lw 8/11

lw 8/15/11

Source: NCI Genomic Data Commons file a31f5779-1e31-4d0b-91ea-cb94e99d1638 (TCGA-BJ-A2P4.A2756544-345C-4797-9DDE-B56048CF0009.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).